Gene-level copy-number profile of tumor specimen TCGA-S2-AA1A-01A from TCGA case TCGA-S2-AA1A, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.2 years (24,903 days).
Specimen TCGA-S2-AA1A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.198a4ba5-8395-404a-8e9c-25e6bcf008af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S2-AA1A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48aa2699-29c7-4151-ae71-fe61afd3f2ab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 2: 142; copy number 3: 899; copy number 4: 31,677; copy number 5: 6,579; copy number 6: 16,495; copy number 7: 979; copy number 8: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S2-AA1A-01A-12D-A396-01): tumor purity 0.32, ploidy 2.41, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:88,430,442–90,112,779, 30 genes: Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
